Gene-level copy-number profile of tumor specimen TCGA-E7-A6MF-01A from TCGA case TCGA-E7-A6MF, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: Low Grade; Age at diagnosis: 38.0 years (13,867 days).
Specimen TCGA-E7-A6MF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.6cca5472-71e6-47db-9332-ca44f355d176.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-E7-A6MF-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c78fd01a-b422-4267-a210-4d8b4d0e0ab8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,380; copy number 2: 57,440.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-E7-A6MF-01A-12D-A32A-01): tumor purity 0.88, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
